Somatic mutation profile of tumor specimen 0DKWNE from CCDI case PBBYUF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.2 years (6,283 days).
Specimen 0DKWNE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c5a0036-20d9-48a9-a827-f52796a58d3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKWNQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6772a98d-9689-42a2-88b1-71d7778e0266

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, 3'UTR 3, Silent 3, Splice Site 2, 5'UTR 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.2530G>A p.G844S | Missense Mutation (SNP) | VAF 566/1832 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1254158878, COSV55089367, COSV55109631; called by muse, mutect2, varscan2
- HMCN2 | c.3716G>A p.W1239* | Nonsense Mutation (SNP) | VAF 45/899 reads (5%) | catalogued as rs1160992521; called by muse, mutect2
- RPS6KA1 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 31/1040 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV64810334; called by muse, mutect2
- C6 | c.2204G>C p.G735A | Missense Mutation (SNP) | VAF 53/1717 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2
- CDH16 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 66/1402 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); called by muse, mutect2
- GPR158 | c.1112-1G>A p.X371_splice | Splice Site (SNP) | VAF 40/765 reads (5%) | called by muse, mutect2
- KIAA1549 | c.2020G>C p.D674H | Missense Mutation (SNP) | VAF 431/2021 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KPNA4 | c.470-1G>A p.X157_splice | Splice Site (SNP) | VAF 85/985 reads (9%) | called by muse, mutect2
- KRT6B | c.1531G>A p.G511R | Missense Mutation (SNP) | VAF 61/2118 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- NSMCE4A | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 54/1520 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.026); called by muse, mutect2
- PTPRK | c.3947_3955del p.R1316_C1318del (on ENST00000368215 / NM_001291984.2; = p.R1317_C1319del on NM_002844.4) | In Frame Del (DEL) | VAF 157/701 reads (22%) | called by pindel, varscan2
- SMG6 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 27/750 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.326); called by muse, mutect2
- SOX2 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 50/553 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- SYCP2 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 54/2152 reads (3%) | SIFT tolerated (0.79); PolyPhen benign (0.074); called by muse, mutect2
- TNRC6B | c.3086G>A p.S1029N (on ENST00000454349 / NM_001162501.2; = p.S976N on NM_015088.3) | Missense Mutation (SNP) | VAF 157/1878 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZFHX4 | c.1870T>C p.S624P | Missense Mutation (SNP) | VAF 34/894 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- ZNF185 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 64/1540 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.268); called by muse, mutect2
- UNC5D | c.621C>T p.N207= | Silent (SNP) | VAF 102/1858 reads (5%) | called by muse, mutect2
- WDR27 | c.588G>A p.P196= | Silent (SNP) | VAF 288/2044 reads (14%) | catalogued as rs369741648; called by muse, mutect2
- WIPF3 | c.279C>T p.S93= | Silent (SNP) | VAF 70/2281 reads (3%) | called by muse, mutect2
- APOH | c.*80G>A | 3'UTR (SNP) | VAF 18/542 reads (3%) | called by muse, mutect2
- DCP2 | c.-14T>C | 5'UTR (SNP) | VAF 36/740 reads (5%) | catalogued as rs1207079849; called by muse, mutect2
- DNAJC6 | c.*71C>T | 3'UTR (SNP) | VAF 34/725 reads (5%) | catalogued as rs1191025180; called by muse, mutect2
- MMP20 | c.*9G>A | 3'UTR (SNP) | VAF 54/1594 reads (3%) | called by muse, mutect2
